TCGA case TCGA-B0-5701 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f8a632d-7fbd-4c86-b909-afb7edb9ad28

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,915 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interleukin-2; Days to treatment start: 366 days (1.0 years); Days to treatment end: 727 days (2.0 years); Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 66.1 years (24,139 days); Days to diagnosis: 224 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 255 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 224 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 224 days.
- Days to follow up: 1,276 days (3.5 years); Disease response: Tumor Free.
- Days to follow up: 1,732 days (4.7 years); Disease response: With Tumor.
- Days to follow up: 2,461 days (6.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Normal.
- Calcium: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-5701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 1.3; Shortest dimension: 0.3.
  Slide TCGA-B0-5701-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-B0-5701-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-B0-5701-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.9; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes.
- Drug treatment: Pharmaceutical therapy drug name: Interleukin-2.
- Follow-up form 1: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,461 days; disease-specific survival: no event (censored), 2,461 days; disease-free interval: event (new tumor event after initially disease-free), 224 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 224 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B0-5701-01A-11D-1530-01): tumor purity 0.57, ploidy 1.99, whole-genome doublings 0.
